MMRF case MMRF_1445 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ec647a73-b91a-4abb-96b2-7f897613884f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.4 years (28,253 days); ISS stage: III; Days to last known disease status: 184 days; Days to last follow up: 184 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 86 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 37 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 133 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2: M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 528 mg/dL; Immunoglobulin G 40.1 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 6.7 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 9.9 g/dL; Glucose 13.2 mmol/L.
- Day 93 (ECOG 1): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 21.9 mg/dL; Immunoglobulin G 17.4 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.05 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 8.14 mmol/L.
- Day 184 (ECOG 0): Hemoglobin 6.7 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 298 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 8.47 mmol/L.

Other clinical attributes
- Day -2: Weight: 61 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_1445_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1445_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
